TARGET case TARGET-50-PAKKSE — High-Risk Wilms Tumor (TARGET-WT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bca5b5c6-5a2c-57ba-b7e9-a67747d00f7b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 2 years; Vital status: Alive.

Diagnoses (1)
1. Wilms tumor: ICD-O-3 morphology code: 8960/3; ICD-10 code: C64; Tissue or organ of origin: Kidney, NOS; Classification of tumor: primary; Age at diagnosis: 2.3 years (847 days); Year of diagnosis: 2000; Days to last follow up: 1,925 days (5.3 years); Pediatric kidney staging: Nephrectomy specimen with tumor that penetrates the renal capsule or involves the renal sinus with negative margins and negative lymph nodes, no distant metastasis; Wilms tumor histologic subtype: Favorable.
   Treatment given: Protocol identifier: NWTS-5.

Follow-up (2 entries)
- Days to follow up: 367 days (1.0 years); Days to first event: 367 days (1.0 years); First event: Relapse.
- Days to follow up: 1,925 days (5.3 years); Year of follow up: 2006.

Biospecimens (3 samples)
- Samples TARGET-50-PAKKSE-01A, TARGET-50-PAKKSE-01B (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-50-PAKKSE-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_WT_ClinicalData_Discovery_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1925
- Stage: II
- ICD-O-3-T: C649
- Histologic Classification of Primary Tumor: FHWT

Additional fields from the TARGET clinical supplement workbook TARGET_WT_ClinicalData_Discovery_and_Validation_Percent_Tumor_Nuclei_and_Necrosis_Supplement_20230322.xlsx (sheet WT Data), for sample TARGET-50-PAKKSE-01A-01:
- Histological Subtype: relapse Wilms
- Specimen Type: frozen solid tumor
- Pathology: Diagnosis Confirmed: yes
- % Tumor Nuclei: Top: 95
- % Non tumor Nuclei: Top: 5
- % Cellular Tumor: Top: 98
- % Normal: Top: 0
- % Stroma: Top: 2
- % Necrosis: Top: 0
- % Tumor Nuclei: Bottom: 95
- % Non tumor Nuclei: Bottom: 5
- % Cellular Tumor: Bottom: 98
- % Normal: Bottom: 0
- % Stroma: Bottom: 2
- % Necrosis: Bottom: 0
- Pathology Pass/Fail: pass

Additional fields from the TARGET clinical supplement workbook TARGET_WT_ClinicalData_Discovery_and_Validation_Percent_Tumor_Nuclei_and_Necrosis_Supplement_20230322.xlsx (sheet WT Data), for sample TARGET-50-PAKKSE-11A-01:
- Histological Subtype: relapse Wilms
- Specimen Type: normal solid tissue
- Pathology: Diagnosis Confirmed: yes
- % Cellular Tumor: Top: 0
- % Normal: Top: 100
- % Stroma: Top: 0
- % Necrosis: Top: 0
- % Cellular Tumor: Bottom: 0
- % Normal: Bottom: 100
- % Stroma: Bottom: 0
- % Necrosis: Bottom: 0
- Pathology Pass/Fail: pass
